MMRF case MMRF_2557 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a517a671-30ac-4c76-b9fb-47b3f82bcbd3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Dead; Days to death: 325 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.5 years (30,508 days); ISS stage: III; Days to last known disease status: 325 days; Days to last follow up: 325 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 222 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 232 days; Days to treatment end: 257 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 251 days; Days to treatment end: 264 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 325.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 141 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.347 mg/dL; Immunoglobulin G 2.11 g/L; Immunoglobulin A 39.7 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 6.8 µg/mL; Lactate Dehydrogenase 1.15 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 181 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.93 mmol/L; Albumin 34 g/L; Total Protein 8.9 g/dL; Glucose 3.96 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 75 (ECOG 1): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 83.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.226 mg/dL; Immunoglobulin G 2.01 g/L; Immunoglobulin A 32.3 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 7.6 µg/mL; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 7.7 g/dL; Glucose 4.79 mmol/L.
- Day 173 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 107 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.233 mg/dL; Immunoglobulin G 0.72 g/L; Immunoglobulin A 24.4 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 7.3 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 257 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 111 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.182 mg/dL; Immunoglobulin G 0.6 g/L; Immunoglobulin A 24.7 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 11.6 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 197 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.48 mmol/L; Albumin 32 g/L; Total Protein 7.6 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -10: Weight: 81 kg; Height: 169 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2557_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2557_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
